Surgical pathology report (de-identified scan), TCGA case TCGA-28-1753, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1753-01A (Primary Tumor).

TCGA-28-1753

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, LEFT PARIETAL, CORE BIOPSY:

- Involved by glioma, part of a glioblastoma multiforme (WHO grade IV)

B. SKULL, SURGICAL HARDWARE REMOVAL:

- Explanted hardware (plates, screws)
- Dense fibrous connective tissue with reactive changes, bone dust and organizing hematoma

C. BRAIN, LEFT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas. Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. between laminin-8 and glial tumor grade, recurrence, and patient survival. Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy. Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma.

Patient Case(s):

Source: NCI Genomic Data Commons file 84638d14-deee-4f17-9d7f-9e0ba65a5244 (TCGA-28-1753.E6085B8D-D1B3-4F2D-A0F4-C8C823ACC762.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).